CPTAC case C3N-03222 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f85a6b6f-f3cb-49f6-a285-3bc3705ae3fb

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 72.9 years (26,630 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 263 days; Progression or recurrence: no; Days to last follow up: 263 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm (a second GDC size field records 5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 15; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 263 days; Disease response: Complete Response.
- Days to follow up: 263 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 85 kg; Height: 175 cm; BMI: 27.76.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 15; Cigarettes per day: 15; Tobacco smoking onset year: 1997; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03222-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -12 days; Initial weight: 200 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03222-21: Section location: Left Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3N-03222-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -12 days; Initial weight: 200 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03222-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
